Surgical pathology report (de-identified scan), TCGA case TCGA-FP-A4BE, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-A4BE-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Final Report Temporary Copy

Case:
Collected
Ordered by:

Pa
Pa
ID

Final Diagnosis

Stomach, excision with frozen sections:

Moderately to poorly differentiated adenocarcinoma.

Neoplasm is present in the serosa.

Maximum tumor diameter 11.9 cm.

Margins of excision appear free of neoplasm in our planes of section.

Marked chronic gastritis.

Twenty-four (24) perigastric lymph nodes are confirmed and are free of carcinoma.

AJCC stage: T3,N0 (stage IIA).

ICD-O-3

New esophageal margin:

No carcinoma identified.

adenocarcinoma, NOS 8140/3

CQCF: site: stomach, fundus C16.1

"Lymph node":

Benign reactive lymph node.

Path site: stomach, NOS C16.9

Peripyloric lymph node:

Benign reactive lymph node.

hw 9/26/12

Level 8 lymph node:

Benign reactive lymph node.

Comment: A previous evaluation for HER-2/neu has been done on biopsy material and will not be repeated. It is noted that material has been sent for evaluation by

Clinical Information

Gastric adenocarcinoma.

Frozen Section Diagnosis

Gastrectomy, 11 x 12 cm fungating invasive neoplasm with necrosis and hemorrhage.

FSA1 (proximal margin):

Esophagus, small probably metastatic deposit.

[page 2 of 2]
Surgical Pathology Final Report

Temporary Copy

Page 2 of 2

Case:

Pa

Collect:

ID:

Ordered by:

Location:

FSA2 (distal margin):

Chronic gastritis, no tumor seen.

Material sent for tumor atlas) and for

FSB (new esophageal margin):

No tumor seen.

Gross Description

"FSA1." All frozen section tissue is submitted in cassette "FSA."

"FSA2." All frozen section tissue is submitted in cassette "FSA2."

"A, NFSA." The specimen consists of a previously opened 19.0 x 17.0 x 3.0 cm gastrectomy specimen. The lesser curvature measures 11.0 cm, and the greater curvature measures 30.3 cm. Previous opening reveals an 11.9 x 11.0 cm tan-brown, fungating, hemorrhagic mass. The radial margin is inked black, the proximal margin is inked orange, and the distal margin is inked blue. The mass grossly appears to come to within 1.0 cm of the esophageal (proximal margin) and 4.1 cm of the distal margin. On sectioning, this mass grossly appears to come to within less than a millimeter of the radial margin. The remaining gastric mucosa is pale tan and roughened with normal rugal folds.

The attached perigastric fat is removed and placed in alcohol to enhance lymph node recovery. On examination, 19 possible lymph nodes are identified within the lesser curvature. These range in size from 0.4 to 2.0 cm. Twenty-four possible lymph nodes are identified within the greater curvature. These range in size from 0.3 to 2.0 cm.

Attached is a 23.2 x 15.8 x 2.5 cm yellow-tan, fatty fragment of omentum. On sectioning, this appears grossly unremarkable.

"A1," distal margin; "A2-A3," mass to include esophageal (proximal margin); "A4-A6," mass to include radial margin; "A7," random sections of pale tan, roughened gastric mucosa with normal rugal folding; "A8-A10," lesser curvature lymph nodes; "A11-A14," greater curvature lymph nodes; "A15," omentum, representative.

"FSB." All frozen section tissue is submitted in cassette "FSB."

"C, Lymph node." The specimen consists of a 1.5 cm yellow-tan, fatty-appearing lymph node. A representative section is submitted into cassette "C."

"D, Peripyloric lymph node." The specimen consists of a 1.2 cm yellow-tan, fatty-appearing lymph node. The specimen is bisected, and a representative section is submitted into cassette "D."

"E, New esophageal margin." The specimen consists of a 1.5 x 1.6 x 1.0 cm tan-brown, focally charred, donut-shaped soft tissue fragment. The serosa has a tan-brown, slightly ragged appearance. The mucosa is gray-tan and unremarkable. This cannot be oriented. One margin is inked black, and the remaining margin is inked orange. "E," fragments, representative.

"F, Level 8 lymph node." Received in formalin is a 2.3 cm tan-brown lymph node. A representative section is submitted into cassette "F."

Performing Lab

Testing performed at

tiPAA Discrepancy		X

W 8/31/12

Source: NCI Genomic Data Commons file 172fa3ac-44c4-49b1-8a36-665133072766 (TCGA-FP-A4BE.D1DD0EA5-448A-4D3A-8E47-7990143284EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).